Gene-level copy-number profile of tumor specimen C3L-04849-02 from CPTAC case C3L-04849, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 63.2 years (23,099 days).
Specimen C3L-04849-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3b7b9b45-e007-4a08-bc31-eab5e101f38c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04849-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/85ecfadd-648f-4e5c-8244-e9d8337b0c23

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 349; copy number 1: 16,941; copy number 2: 32,029; copy number 3: 8,640; copy number 4: 542; copy number 5: 67; copy number 6: 157; copy number 7: 12; copy number 9: 13; copy number 10: 29; copy number 12: 82; copy number 13: 16; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 377 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:63,465,511–66,150,012, 25 genes, copy number 5–7: AC093730.1, TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, LINC02232, AC107058.1, EFL1P2, AC096754.1, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1.
- chr6:29,934,101–29,934,286, 1 gene, copy number 7: HLA-U.
- chr8:116,950,273–117,176,714, 1 gene, copy number 6 (within-gene range 4–6): SLC30A8.
- chr8:117,055,818–118,622,112, 10 genes, copy number 6 (within-gene range 4–6): AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1.
- chr8:122,781,655–122,974,510, 1 gene, copy number 6 (within-gene range 4–6): ZHX2.
- chr8:122,977,026–124,728,473, 52 genes, copy number 6: AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1.
- chr8:124,821,978–135,299,719, 144 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:68,903,863–72,843,674, 141 genes, copy number 9–22 (within-gene range 1–22) (broad region; genes not listed).
- chr13:73,399,031–73,408,352, 2 genes, copy number 5: AL162376.1, MARK2P12.

Autosomal genes at a single copy (total copy number 1): 14,478. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
